Somatic mutation profile of tumor specimen TCGA-EB-A85I-01A (aliquot TCGA-EB-A85I-01A-11D-A34U-08) from TCGA case TCGA-EB-A85I, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 66.8 years (24,408 days).
Specimen TCGA-EB-A85I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8af0eeec-a19c-461e-9915-50d31f573688.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A85I-10B (Blood Derived Normal), aliquot TCGA-EB-A85I-10B-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d3f5e6a-bda2-4b03-8f0a-be1f8a624e88

The open-access MAF lists 261 somatic variants for this specimen: 160 protein-altering or splice-affecting, 91 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 140, Silent 91, Nonsense Mutation 10, Splice Region 5, 5'UTR 3, Intron 3, Splice Site 3, 5'Flank 2, RNA 2, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- NIPBL | c.2494C>T p.R832* | Nonsense Mutation (SNP) | VAF 10/67 reads (15%) | catalogued as rs587783906, CM042509, COSV56943778, COSV56946160; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AARS1 | c.1995C>T p.A665= | Splice Region (SNP) | VAF 3/13 reads (23%) | catalogued as rs754212203, COSV55748156, COSV99933783; ClinVar: likely benign; called by muse, mutect2
- ACE | c.1558C>T p.H520Y | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52011950; called by muse, mutect2, varscan2
- ACSM3 | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99184949; called by muse, mutect2, varscan2
- ADAM29 | c.959A>G p.N320S | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as COSV100822234; called by muse, mutect2, varscan2
- ADH1A | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 97/355 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); catalogued as COSV52924354; called by muse, mutect2, varscan2
- AHSA1 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as rs780308322, COSV99376202; called by muse, mutect2, varscan2
- AK9 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.561); catalogued as COSV99572628; called by muse, mutect2, varscan2
- ASTN1 | c.1066G>A p.D356N | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.234); catalogued as rs267598198, COSV56067864, COSV99920404; called by muse, mutect2, varscan2
- ATP1A3 | c.244G>A p.A82T (on ENST00000545399 / NM_001256214.2; = p.A69T on NM_152296.5) | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV57485217; called by muse, mutect2, varscan2
- BOD1L1 | c.8362C>T p.P2788S | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.063); catalogued as COSV99240354; called by muse, mutect2, varscan2
- BRCA1 | c.2618C>T p.S873L | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1567794912, COSV100525022; ClinVar: uncertain significance; called by muse, mutect2
- BRD2 | c.343A>T p.K115* | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as COSV100875827; called by muse, mutect2, varscan2
- C10orf71 | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.677); catalogued as COSV100110625; called by muse, mutect2, varscan2
- C12orf40 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100210747, COSV61131405; called by muse, mutect2, varscan2
- C8B | c.1505C>T p.S502F | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV64776531; called by muse, mutect2, varscan2
- CACNA1E | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100705175; called by muse, mutect2, varscan2
- CACNA1S | c.4037C>T p.P1346L | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as rs1370373504, COSV100755361, COSV100755470; called by muse, mutect2, varscan2
- CALCR | c.890G>T p.R297M (on ENST00000649521 / NM_001164737.2; = p.R281M on NM_001742.4) | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100810847; called by muse, mutect2
- CCSER2 | c.2356T>C p.W786R | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99826477; called by muse, mutect2, varscan2
- CDC25B | c.674C>T p.A225V (on ENST00000245960 / NM_021873.3; = p.A211V on NM_004358.4) | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.047); catalogued as COSV99848362; called by muse, mutect2, varscan2
- CFAP100 | c.1603G>A p.A535T | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.044); catalogued as COSV100729422; called by muse, mutect2, varscan2
- CFHR5 | c.1663C>T p.R555* | Nonsense Mutation (SNP) | VAF 13/74 reads (18%) | catalogued as rs780410370, COSV56820683; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CFI | c.1555G>A p.D519N | Missense Mutation (SNP) | VAF 72/239 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs121964918, CM062508, COSV101144712; ClinVar: risk factor; called by muse, mutect2, varscan2
- CHRNA4 | c.531G>A p.M177I | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV100937478; called by muse, mutect2, varscan2
- CNGB3 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 55/269 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.957); catalogued as rs777404947, COSV60686170; called by muse, mutect2, varscan2
- COL27A1 | c.2600C>T p.P867L | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT tolerated (0.9); PolyPhen benign (0.038); catalogued as rs775112782, COSV100621310; called by muse, mutect2, varscan2
- CPLANE1 | c.8960C>T p.P2987L | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); catalogued as COSV99951654; called by muse, mutect2, varscan2
- CREB3L1 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV55830552; called by muse, mutect2, varscan2
- CTSC | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs756131048, COSV99910967; called by muse, mutect2
- DACH1 | c.1324C>T p.P442S (on ENST00000619232 / NM_001366712.1; = p.P390S on NM_080759.6) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.742); catalogued as rs747753827, COSV57493215; called by muse, mutect2, varscan2
- DCLK2 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV56198611; called by muse, mutect2, varscan2
- DNAH5 | c.11906G>A p.W3969* | Nonsense Mutation (SNP) | VAF 18/75 reads (24%) | catalogued as COSV99453951; called by muse, mutect2, varscan2
- DXO | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100514846; called by muse, mutect2, varscan2
- EEF2KMT | c.313T>A p.S105T | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV101435310; called by muse, mutect2, varscan2
- EIF3E | c.181C>T p.L61F | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99623501; called by muse, mutect2, varscan2
- ESRP2 | c.1754C>T p.P585L (on ENST00000565858 / NM_001365264.1; = p.P575L on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.411); catalogued as COSV99251478; called by muse, mutect2, varscan2
- FABP1 | c.305C>T p.T102I | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as COSV99860966; called by muse, mutect2, varscan2
- FAM47B | c.1112C>T p.T371I | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV100264619; called by muse, mutect2, varscan2
- FAM47B | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 49/92 reads (53%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV100264617, COSV100264620; called by muse, mutect2, varscan2
- FAM90A1 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 50/270 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.288); catalogued as rs771934323, COSV100274514; called by muse, mutect2, varscan2
- FAT3 | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT tolerated (0.2); PolyPhen probably damaging (1); catalogued as COSV99970740; called by muse, mutect2, varscan2
- FAT4 | c.8551G>A p.D2851N | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100630069; called by muse, mutect2, varscan2
- FBLN2 | c.1882C>T p.H628Y | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as COSV99852578; called by muse, mutect2, varscan2
- FBXO39 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as rs536953500, COSV58620938, COSV58622853; called by muse, mutect2, varscan2
- FGD6 | c.1478G>A p.R493Q | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as rs1045074245, COSV59691619; called by muse, mutect2, varscan2
- FUT5 | c.435G>A p.W145* | Nonsense Mutation (SNP) | VAF 17/66 reads (26%) | catalogued as COSV53137691; called by muse, mutect2, varscan2
- FUT9 | c.235C>T p.L79F | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.282); catalogued as COSV56142731, COSV56157944; called by muse, mutect2, varscan2
- GALNT13 | c.370C>T p.H124Y | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1366785930, COSV67231091; called by muse, mutect2, varscan2
- GAS2L2 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as rs1342756079; called by muse, mutect2, varscan2
- GCN1 | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.432); catalogued as COSV100325946; called by muse, mutect2, varscan2
- GCSAML | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 3/17 reads (18%) | catalogued as COSV100825980, COSV100826040; called by muse, mutect2
- GSG1L | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs867273348, COSV101094609, COSV101095251; called by muse, mutect2
- GUCA2B | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.393); catalogued as COSV101001851; called by muse, mutect2, varscan2
- GUCY2D | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs774767443, COSV54697907; called by muse, mutect2, varscan2
- HBG2 | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.774); catalogued as COSV57963186, COSV57964307; called by muse, mutect2, varscan2
- HEATR5B | c.2845C>A p.P949T | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.499); catalogued as rs760728880, COSV51857424, COSV51859556; called by muse, mutect2, varscan2
- HK3 | c.1729G>T p.G577W | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99459298; called by muse, mutect2, varscan2
- HTR7 | c.1130C>T p.S377F | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53293871; called by muse, mutect2, varscan2
- IGSF5 | c.957G>A p.K319= | Splice Region (SNP) | VAF 5/30 reads (17%) | catalogued as COSV66030182; called by muse, mutect2, varscan2
- IRGC | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.077); catalogued as COSV99746525; called by muse, mutect2, varscan2
- KAZN | c.1247C>A p.T416K | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.238); catalogued as rs1557793580, COSV101057090, COSV65715015; called by muse, mutect2, varscan2
- KLF15 | c.1232C>T p.S411F | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV99955066; called by muse, mutect2, varscan2
- KLHL8 | c.1565G>T p.S522I | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV99911575; called by muse, mutect2, varscan2
- LGR5 | c.1281-1G>A p.X427_splice | Splice Site (SNP) | VAF 38/135 reads (28%) | catalogued as COSV99878474; called by muse, mutect2, varscan2
- LILRB4 | c.987C>T p.F329= | Splice Region (SNP) | VAF 12/29 reads (41%) | catalogued as COSV54409077; called by muse, mutect2, varscan2
- LINGO2 | c.484G>C p.D162H | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100431189; called by muse, mutect2, varscan2
- LRP2 | c.10639C>T p.L3547F | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.784); catalogued as COSV99790189; called by muse, mutect2, varscan2
- LRRC42 | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as rs752102206, COSV100066716; called by muse, mutect2, varscan2
- LRRC74A | c.151T>A p.S51T | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV99372729; called by muse, mutect2, varscan2
- LSR | c.1528A>G p.S510G (on ENST00000361790; = p.S491G on NM_015925.6) | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV99723505; called by muse, mutect2, varscan2
- LTN1 | c.4834T>A p.S1612T | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as COSV100798194; called by muse, mutect2, varscan2
- LY6G5B | c.554C>T p.S185L | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV101020856; called by muse, mutect2, varscan2
- LYVE1 | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 61/249 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as rs1191090779, COSV56282315; called by muse, mutect2, varscan2
- MAT2B | c.893C>T p.S298F | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99796903; called by muse, mutect2, varscan2
- MBD3L1 | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as COSV99978056; called by muse, mutect2, varscan2
- MCM6 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201824504, COSV99919373; called by muse, mutect2, varscan2
- MERTK | c.937C>T p.P313S | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.619); catalogued as COSV99775268; called by muse, mutect2, varscan2
- MGA | c.6811C>T p.Q2271* (on ENST00000219905 / NM_001164273.1; = p.Q2062* on NM_001080541.2) | Nonsense Mutation (SNP) | VAF 10/54 reads (19%) | catalogued as COSV54953182; called by muse, mutect2, varscan2
- MGAM | c.1835G>A p.R612H | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369813631; called by muse, mutect2, varscan2
- MGAM | c.1954C>T p.P652S | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as COSV101527737; called by muse, mutect2, varscan2
- MINDY3 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as rs776784319, COSV53219143; called by muse, mutect2, varscan2
- MMP27 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.141); catalogued as rs139015378; called by muse, mutect2, varscan2
- MRAP | c.242G>A p.S81N | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as rs1270689130, COSV100353336; called by muse, mutect2, varscan2
- MUC16 | c.42307G>A p.E14103K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated, low confidence (0.33); PolyPhen probably damaging (0.961); catalogued as rs552173997, COSV101109401, COSV66694165; called by muse, mutect2, varscan2
- MUC16 | c.12203C>T p.S4068L | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.106); catalogued as rs1290274710, COSV67463283; called by muse, mutect2, varscan2
- MUC16 | c.299G>A p.R100K | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.045); catalogued as COSV101201521, COSV67482837; called by muse, mutect2, varscan2
- MXRA5 | c.5194T>G p.F1732V | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV99479119; called by muse, mutect2
- MYO3A | c.2823G>T p.M941I | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99781459; called by muse, mutect2, varscan2
- MYOF | c.2750G>A p.R917K | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV100826104, COSV63705632; called by muse, mutect2, varscan2
- NADK | c.1055C>T p.S352L | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100411045; called by muse, mutect2, varscan2
- NCF2 | c.609G>A p.T203= | Splice Region (SNP) | VAF 43/154 reads (28%) | catalogued as rs147657171, COSV62316343; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NFYC | c.247C>T p.R83* | Nonsense Mutation (SNP) | VAF 36/128 reads (28%) | catalogued as rs779107990, COSV100438147; called by muse, mutect2, varscan2
- NIN | c.6203C>T p.P2068L (on ENST00000382041 / NM_182946.1; = p.P1355L on NM_016350.4) | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.012); catalogued as rs897529297, COSV99815162; called by muse, mutect2, varscan2
- NLRP10 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.155); catalogued as COSV60780591; called by muse, mutect2, varscan2
- NYAP2 | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138393299, COSV56002081; called by muse, mutect2, varscan2
- OR2F2 | c.256C>T p.L86F | Missense Mutation (SNP) | VAF 110/282 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV101283854; called by muse, mutect2, varscan2
- OR4L1 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs772817849, COSV59849231, COSV59851325; called by muse, mutect2, varscan2
- OR5D18 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 57/191 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV61736333; called by muse, mutect2, varscan2
- OR5T3 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100282921; called by muse, mutect2, varscan2
- OR7E24 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV101509687; called by muse, mutect2, varscan2
- OR8K1 | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.078); catalogued as COSV54404599; called by muse, mutect2, varscan2
- OTC | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1057515879, COSV50000849; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OTOGL | c.5318G>T p.W1773L (on ENST00000547103; = p.W1764L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.79); PolyPhen benign (0.026); catalogued as COSV100087790; called by muse, mutect2, varscan2
- PCDH15 | c.4828G>A p.E1610K | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.005); catalogued as COSV100227257; called by muse, mutect2, varscan2
- PCDH17 | c.3004G>A p.G1002R | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100931740, COSV100932024; called by muse, mutect2, varscan2
- PCDHA7 | c.94C>T p.H32Y | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); catalogued as rs1554134251, COSV100971774; called by muse, mutect2, varscan2
- PCMTD1 | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100859793; called by muse, mutect2, varscan2
- PCNX2 | c.4490G>A p.W1497* | Nonsense Mutation (SNP) | VAF 33/105 reads (31%) | catalogued as COSV99269391; called by muse, mutect2, varscan2
- PDCD1 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100545567; called by muse, mutect2, varscan2
- PDGFRL | c.110G>A p.R37K | Missense Mutation (SNP) | VAF 44/171 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV99286678; called by muse, mutect2, varscan2
- PEAR1 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV52776288; called by muse, mutect2, varscan2
- PEG3 | c.3211G>A p.E1071K | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs772073875, COSV99690323; called by muse, mutect2, varscan2
- PKHD1L1 | c.8365C>T p.R2789C | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs377699317; called by muse, mutect2, varscan2
- PLEK | c.1045G>T p.G349W | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99311227; called by muse, mutect2, varscan2
- PLEKHG7 | c.302C>A p.P101H | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV101188879; called by muse, mutect2, varscan2
- PNPLA7 | c.2825G>A p.G942D | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99481384; called by muse, mutect2, varscan2
- PPP1R12B | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100408427; called by muse, mutect2, varscan2
- PRKDC | c.2197C>T p.L733F | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as rs1311346330, COSV100042734; called by muse, mutect2, varscan2
- PRR23B | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.017); catalogued as COSV100272212; called by muse, mutect2, varscan2
- PRRC2C | c.4094C>A p.S1365Y (on ENST00000367742; = p.S1363Y on NM_015172.4) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.1); catalogued as COSV100146004; called by muse, mutect2, varscan2
- PRSS23 | c.83G>T p.W28L | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.72); PolyPhen benign (0.034); catalogued as COSV99722577; called by muse, mutect2, varscan2
- PTDSS1 | c.968G>A p.R323K | Missense Mutation (SNP) | VAF 40/185 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100428933; called by muse, mutect2, varscan2
- PTH2R | c.1600G>A p.E534K | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV55915452; called by muse, mutect2, varscan2
- RAB37 | c.367-1G>A p.X123_splice (on ENST00000392613 / NM_001006638.3; = p.X116_splice on NM_175738.5) | Splice Site (SNP) | VAF 14/58 reads (24%) | catalogued as COSV52853005; called by muse, mutect2, varscan2
- RANBP17 | c.1129C>T p.H377Y | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.463); catalogued as COSV101206219, COSV101206377; called by muse, mutect2, varscan2
- RFC4 | c.998A>G p.E333G | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.424); catalogued as COSV99961371; called by muse, mutect2, varscan2
- RIPOR3 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50385924; called by muse, mutect2, varscan2
- RLBP1 | c.526-1G>A p.X176_splice | Splice Site (SNP) | VAF 25/57 reads (44%) | catalogued as COSV99175400; called by muse, mutect2, varscan2
- RSPO2 | c.284G>A p.R95K | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (1); PolyPhen probably damaging (0.969); catalogued as COSV99410348; called by muse, mutect2
- SALL4 | c.2345C>T p.T782I | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV99409827; called by muse, mutect2, varscan2
- SAMD9 | c.4529C>T p.S1510F | Missense Mutation (SNP) | VAF 75/148 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV66076413; called by muse, mutect2, varscan2
- SERPINA5 | c.1076G>A p.G359E | Missense Mutation (SNP) | VAF 69/200 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100291811; called by muse, mutect2, varscan2
- SLC22A9 | c.1049G>A p.R350K | Missense Mutation (SNP) | VAF 42/200 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV99654820, COSV99655363; called by muse, mutect2, varscan2
- SLC23A2 | c.1252G>A p.G418R | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100595282; called by muse, mutect2, varscan2
- SLC25A11 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52591038; called by muse, mutect2, varscan2
- SLC9A4 | c.1234C>T p.R412W | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766908354, COSV54828977; called by muse, mutect2, varscan2
- SLITRK6 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.975); catalogued as COSV101233292; called by muse, mutect2, varscan2
- SMC4 | c.3505C>T p.P1169S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100557574; called by muse, mutect2, varscan2
- SPHKAP | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771332747, COSV100764525; called by muse, mutect2, varscan2
- SULT1C4 | c.283T>C p.S95P | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV99731791; called by muse, mutect2, varscan2
- THBS3 | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 68/231 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as rs778493768, COSV100857706; called by muse, mutect2, varscan2
- THEMIS | c.294G>A p.M98I | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs201146745, COSV64070718; called by muse, mutect2, varscan2
- THSD7B | c.3067C>T p.R1023* | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | catalogued as rs750153977, COSV55661886; called by muse, mutect2, varscan2
- THSD7B | c.3710G>A p.R1237K (on ENST00000272643; = p.R1235K on NM_001316349.2) | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV99757849; called by muse, mutect2, varscan2
- TPD52 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); catalogued as COSV100990887; called by muse, mutect2, varscan2
- TRPM8 | c.1520G>A p.R507Q | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as rs201095192, COSV61222045; called by muse, mutect2, varscan2
- TSHZ2 | c.1822G>A p.D608N | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV100296736; called by muse, mutect2, varscan2
- TSPAN2 | c.72G>A p.L24= | Splice Region (SNP) | VAF 8/16 reads (50%) | catalogued as COSV101050084; called by muse, mutect2, varscan2
- TTN | c.20849G>C p.G6950A (on ENST00000591111; = p.G6023A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | PolyPhen possibly damaging (0.652); catalogued as COSV100628967; called by muse, mutect2, varscan2
- UBR1 | c.2452C>T p.H818Y | Missense Mutation (SNP) | VAF 48/214 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99317830; called by muse, mutect2, varscan2
- UBR2 | c.1202G>A p.R401K | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100867519; called by muse, mutect2, varscan2
- VCAN | c.5188G>A p.G1730R | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0.014); catalogued as COSV99425773, COSV99427222; called by muse, mutect2, varscan2
- WDR64 | c.2963C>T p.P988L | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100844024; called by muse, mutect2, varscan2
- ZNF514 | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 50/196 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.069); catalogued as COSV54634189; called by muse, mutect2, varscan2
- ZNF607 | c.1222C>T p.L408F | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1289871063, COSV100777955; called by muse, mutect2, varscan2
- ZNF862 | c.2936C>T p.S979F | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs780096302, COSV99783793; called by muse, mutect2, varscan2
- IPO9 | c.2697dup p.K900* | Frame Shift Ins (INS) | VAF 10/51 reads (20%) | called by mutect2, pindel, varscan2
- PNPLA8 | c.686_687delinsC p.H229Pfs*13 | Frame Shift Del (DEL) | VAF 22/92 reads (24%) | called by pindel, varscan2*
- ACACB | c.4875C>T p.L1625= | Silent (SNP) | VAF 51/185 reads (28%) | catalogued as rs148547674, COSV58147525; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4176G>A p.P1392= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs202124252, COSV65877936; called by muse, mutect2, varscan2
- ANK1 | c.3682C>T p.L1228= | Silent (SNP) | VAF 39/189 reads (21%) | catalogued as COSV55879306, COSV99052324, COSV99226757; called by muse, mutect2, varscan2
- ARMC10 | c.930C>T p.F310= | Silent (SNP) | VAF 18/145 reads (12%) | catalogued as rs1340690295, COSV100085831; called by muse, mutect2, varscan2
- BBS2 | c.399C>T p.S133= | Silent (SNP) | VAF 22/108 reads (20%) | catalogued as rs775477661, COSV99802815; called by muse, mutect2
- BHLHE22 | c.849C>T p.I283= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV58861435; called by muse, mutect2
- C1orf112 | c.627C>T p.S209= | Silent (SNP) | VAF 34/120 reads (28%) | catalogued as COSV99610168; called by muse, mutect2, varscan2
- CCDC105 | c.633G>A p.R211= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV52963091; called by muse, mutect2, varscan2
- CDK20 | c.459C>T p.S153= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV57482308; called by muse, mutect2, varscan2
- CEL | c.933C>T p.V311= (on ENST00000673714; = p.V308= on NM_001807.6) | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV100672780; called by muse, mutect2, varscan2
- CEP350 | c.5626C>T p.L1876= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV62598984; called by muse, mutect2, varscan2
- CHRM4 | c.825C>T p.A275= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV100708784, COSV100708873; called by muse, mutect2, varscan2
- COL17A1 | c.2835C>T p.F945= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs144329737; called by muse, mutect2, varscan2
- COL21A1 | c.1527G>A p.G509= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV99778617; called by muse, mutect2, varscan2
- CSMD2 | c.8535C>T p.I2845= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV53964900; called by muse, mutect2, varscan2
- CSMD2 | c.3384C>T p.I1128= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as COSV99594980; called by muse, mutect2, varscan2
- CTSC | c.966C>T p.F322= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as COSV99910804, COSV99910969; called by muse, mutect2
- DNAH5 | c.6942T>C p.D2314= | Silent (SNP) | VAF 25/99 reads (25%) | catalogued as COSV54236245, COSV99453955; called by muse, mutect2, varscan2
- DNAH9 | c.3162C>T p.L1054= | Silent (SNP) | VAF 29/104 reads (28%) | catalogued as COSV52358150, COSV99307962; called by muse, mutect2, varscan2
- EMB | c.633G>A p.V211= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV57484209; called by muse, mutect2, varscan2
- EPHB2 | c.1272C>T p.F424= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as rs778869890, COSV65865180; called by muse, mutect2, varscan2
- EVI5L | c.369C>T p.I123= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV54488331; called by muse, mutect2, varscan2
- FARSA | c.1245C>A p.P415= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as COSV100108958; called by muse, mutect2, varscan2
- GPR139 | c.210T>G p.A70= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV100430031; called by muse, mutect2, varscan2
- HEATR5A | c.1194C>G p.A398= | Silent (SNP) | VAF 41/175 reads (23%) | catalogued as COSV101120522, COSV66341757; called by muse, mutect2, varscan2
- HECW1 | c.3816G>A p.R1272= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV67838408; called by muse, mutect2, varscan2
- IL21R | c.585C>T p.S195= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV100560582; called by muse, mutect2, varscan2
- KCND3 | c.48C>T p.A16= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV100137060, COSV100138399; called by muse, mutect2, varscan2
- KCTD21 | c.417C>T p.S139= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV100399800; called by muse, mutect2, varscan2
- KLF15 | c.1233C>T p.S411= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as rs758209681, COSV99955364; called by muse, mutect2, varscan2
- KRTAP5-10 | c.66G>A p.G22= | Silent (SNP) | VAF 46/146 reads (32%) | catalogued as COSV100924164; called by muse, mutect2, varscan2
- L3MBTL3 | c.1509C>T p.H503= | Silent (SNP) | VAF 57/253 reads (23%) | catalogued as rs145533962; called by muse, mutect2, varscan2
- LINGO2 | c.183C>T p.I61= | Silent (SNP) | VAF 51/110 reads (46%) | catalogued as COSV58059148, COSV58064362; called by muse, mutect2, varscan2
- LYST | c.7374T>C p.C2458= | Silent (SNP) | VAF 38/83 reads (46%) | catalogued as COSV101090257; called by muse, mutect2, varscan2
- MAN2B2 | c.2193A>T p.S731= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV99578031; called by muse, mutect2, varscan2
- MAPK8IP3 | c.2637C>T p.A879= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as COSV99169692; called by muse, mutect2, varscan2
- MROH2B | c.4527C>T p.S1509= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs373543947; called by muse, mutect2, varscan2
- MSH2 | c.555C>T p.S185= | Silent (SNP) | VAF 50/164 reads (30%) | catalogued as COSV99254512; called by muse, mutect2, varscan2
- MUC15 | c.936A>G p.P312= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV99846665; called by muse, mutect2, varscan2
- MUC16 | c.39741C>T p.I13247= | Silent (SNP) | VAF 34/106 reads (32%) | catalogued as rs748430485, COSV66690351; called by muse, mutect2, varscan2
- MXRA5 | c.5196C>T p.F1732= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as COSV54249338; called by muse, mutect2
- NALCN | c.363T>C p.S121= | Silent (SNP) | VAF 14/146 reads (10%) | catalogued as COSV99217551; called by muse, mutect2, varscan2
- NYNRIN | c.3987C>T p.L1329= | Silent (SNP) | VAF 48/192 reads (25%) | catalogued as COSV101230698; called by muse, mutect2, varscan2
- OR10A3 | c.42C>T p.L14= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as rs766384859, COSV62460035; called by muse, mutect2, varscan2
- OR10H1 | c.234C>T p.I78= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV58472766; called by muse, mutect2, varscan2
- OR11L1 | c.960C>T p.F320= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV63313830; called by muse, mutect2, varscan2
- OR2F1 | c.165C>T p.L55= | Silent (SNP) | VAF 78/348 reads (22%) | catalogued as rs1181699853, COSV67331808; called by muse, mutect2, varscan2
- OR4B1 | c.876G>A p.V292= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV58881785; called by muse, mutect2, varscan2
- OR4K17 | c.198C>T p.L66= | Silent (SNP) | VAF 61/268 reads (23%) | catalogued as COSV59647724, COSV59647955; called by muse, mutect2, varscan2
- OR51F2 | c.192C>T p.F64= | Silent (SNP) | VAF 36/167 reads (22%) | catalogued as rs557130556, COSV100437960, COSV59066362; called by muse, mutect2, varscan2
- OR51G1 | c.279G>A p.E93= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs780432992, COSV58970396; called by muse, mutect2
- OR7G3 | c.648C>T p.F216= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as rs749945841, COSV100555749; called by muse, mutect2, varscan2
- OR8G1 | c.642C>T p.I214= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as COSV100422655; called by muse, mutect2, varscan2
- PCDH15 | c.234G>A p.K78= | Silent (SNP) | VAF 36/113 reads (32%) | catalogued as COSV100226890, COSV100227258; called by muse, mutect2, varscan2
- PCDHB10 | c.268C>T p.L90= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV99505007; called by muse, mutect2, varscan2
- PLCB4 | c.2037C>T p.F679= | Silent (SNP) | VAF 38/140 reads (27%) | catalogued as COSV53796241; called by muse, mutect2, varscan2
- PLCD4 | c.1032G>A p.G344= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV101346961; called by muse, mutect2, varscan2
- PLEKHG7 | c.303C>A p.P101= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV101188880; called by muse, mutect2, varscan2
- PNMA3 | c.828A>G p.Q276= | Silent (SNP) | VAF 33/70 reads (47%) | catalogued as COSV100937667; called by muse, mutect2, varscan2
- PPP1R26 | c.1299C>T p.T433= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV63355159; called by muse, mutect2
- PRDM9 | c.519G>A p.K173= | Silent (SNP) | VAF 27/149 reads (18%) | catalogued as COSV57004200; called by muse, mutect2, varscan2
- PTPRC | c.288T>C p.F96= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as rs769834579, COSV100723150; called by muse, mutect2, varscan2
- SALL3 | c.2202C>T p.P734= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as rs752301302, COSV101610055; called by muse, mutect2, varscan2
- SALL4 | c.729C>T p.A243= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as rs1192768058, COSV99409829; called by muse, mutect2, varscan2
- SCN5A | c.861C>T p.L287= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV100350458; called by muse, mutect2, varscan2
- SDK1 | c.5457C>T p.N1819= | Silent (SNP) | VAF 27/117 reads (23%) | catalogued as rs763350023, COSV67388035; called by muse, mutect2, varscan2
- SLC10A5 | c.588T>A p.S196= | Silent (SNP) | VAF 26/127 reads (20%) | catalogued as COSV101594271; called by muse, mutect2, varscan2
- SLC22A14 | c.867C>T p.I289= | Silent (SNP) | VAF 34/138 reads (25%) | catalogued as rs769090429, COSV56196111; called by muse, mutect2, varscan2
- SLC26A9 | c.508C>T p.L170= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs1246007193, COSV100536755; called by muse, mutect2, varscan2
- SLC9A4 | c.345C>T p.F115= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as rs1414664004, COSV99763526; called by muse, mutect2, varscan2
- SLITRK1 | c.385C>T p.L129= | Silent (SNP) | VAF 35/136 reads (26%) | catalogued as COSV101000058; called by muse, mutect2, varscan2
- SPANXN2 | c.183G>A p.T61= | Silent (SNP) | VAF 72/130 reads (55%) | catalogued as rs782774590, COSV65127684; called by muse, mutect2, varscan2
- SYTL2 | c.1044C>T p.I348= | Silent (SNP) | VAF 26/119 reads (22%) | catalogued as COSV100314945; called by muse, mutect2, varscan2
- TARS3 | c.2184C>T p.D728= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as rs756472956, COSV60108007; called by muse, mutect2
- TBC1D9 | c.3306C>T p.G1102= | Silent (SNP) | VAF 3/47 reads (6%) | catalogued as rs1348596164, COSV101464399; called by muse, mutect2
- TGM2 | c.840C>T p.F280= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs768320957, COSV100821748; called by muse, mutect2, varscan2
- TINAG | c.1155C>T p.F385= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as rs1300632056, COSV99450794; called by muse, mutect2, varscan2
- TOGARAM2 | c.444G>A p.G148= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV101091467; called by muse, mutect2
- TPTE | c.1005G>A p.A335= (on ENST00000618007 / NM_199261.4; = p.A317= on NM_199259.4) | Silent (SNP) | VAF 28/336 reads (8%) | catalogued as rs755583335; called by muse, mutect2
- TRAPPC9 | c.3300G>T p.S1100= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as COSV101228336, COSV66898969; called by muse, mutect2, varscan2
- TRIM54 | c.117C>T p.I39= | Silent (SNP) | VAF 56/219 reads (26%) | catalogued as COSV99940652; called by muse, mutect2, varscan2
- TRIP4 | c.432G>A p.K144= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as COSV99974921; called by muse, mutect2, varscan2
- TRRAP | c.840C>T p.F280= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as rs781966222, COSV62848295; called by muse, mutect2, varscan2
- USP16 | c.558C>T p.P186= | Silent (SNP) | VAF 18/91 reads (20%) | catalogued as COSV100538084; called by muse, mutect2, varscan2
- VPS13A | c.2400A>G p.E800= | Silent (SNP) | VAF 32/81 reads (40%) | catalogued as COSV100653492; called by muse, mutect2, varscan2
- ZC3HAV1 | c.2301C>A p.L767= | Silent (SNP) | VAF 25/136 reads (18%) | catalogued as COSV54299885, COSV99649060; called by muse, mutect2, varscan2
- ZFPM2 | c.900C>T p.F300= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as COSV65875837; called by muse, mutect2, varscan2
- ZNF106 | c.5166C>T p.V1722= | Silent (SNP) | VAF 21/92 reads (23%) | catalogued as COSV99783143; called by muse, mutect2, varscan2
- ZNF410 | c.951C>T p.G317= | Silent (SNP) | VAF 60/166 reads (36%) | catalogued as rs1233890039, COSV100206594; called by muse, mutect2, varscan2
- ZNF608 | c.4392C>T p.H1464= | Silent (SNP) | VAF 54/208 reads (26%) | catalogued as rs777892028, COSV100102391; called by muse, mutect2, varscan2
- ZNF804B | c.549C>T p.S183= | Silent (SNP) | VAF 16/103 reads (16%) | catalogued as rs952466840, COSV60816683; called by muse, mutect2, varscan2
- AC024940.1 | n.5586C>T | RNA (SNP) | VAF 15/57 reads (26%) | catalogued as rs1456769338; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498710 G>A | 5'Flank (SNP) | VAF 49/186 reads (26%) | called by muse, mutect2, varscan2
- ARID1B | c.3096+887C>T | Intron (SNP) | VAF 22/104 reads (21%) | catalogued as COSV99271784; called by muse, mutect2
- ARIH2 | c.-317G>T | 5'UTR (SNP) | VAF 8/17 reads (47%) | catalogued as COSV100711403; called by muse, mutect2, varscan2
- CFAP47 | c.5536-459C>T | Intron (SNP) | VAF 11/19 reads (58%) | catalogued as COSV57977397; called by muse, mutect2, varscan2
- FGF13 | c.403-32105C>T | Intron (SNP) | VAF 12/18 reads (67%) | catalogued as COSV100264592; called by muse, mutect2, varscan2
- KLRA1P | n.650C>T | RNA (SNP) | VAF 17/63 reads (27%) | called by muse, mutect2, varscan2
- LOXL2 | c.-2G>A | 5'UTR (SNP) | VAF 10/43 reads (23%) | catalogued as COSV101207985; called by muse, mutect2, varscan2
- RN7SL545P | chr15:22431975 G>A | 5'Flank (SNP) | VAF 34/200 reads (17%) | catalogued as rs544394310; called by mutect2, varscan2
- SCN1A | c.-1G>A | 5'UTR (SNP) | VAF 37/115 reads (32%) | catalogued as COSV100321994; called by muse, mutect2, varscan2
